Somatic mutation profile of tumor specimen TARGET-40-PATAWV-01A (aliquot TARGET-40-PATAWV-01A-01D) from TARGET case TARGET-40-PATAWV, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.5 years (5,667 days).
Specimen TARGET-40-PATAWV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 273bb4a8-4c4a-4380-b2e3-9ffa2db12171.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATAWV-10A (Blood Derived Normal), aliquot TARGET-40-PATAWV-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa995f07-ab38-4774-bcc1-c8997b44c589

The open-access MAF lists 32 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Intron 5, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPEP3 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.074); catalogued as rs780496390, COSV99262969; called by muse, mutect2, varscan2
- HHLA1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs369994118; called by muse, mutect2, varscan2
- MUC4 | c.3399C>G p.H1133Q | Missense Mutation (SNP) | VAF 46/543 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.702); catalogued as rs747366842, COSV62208627; called by muse, varscan2
- POTEH | c.982T>G p.L328V | Missense Mutation (SNP) | VAF 32/770 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100624628, COSV58880181; called by muse, mutect2
- ALMS1 | c.11032_11036del p.R3678* | Frame Shift Del (DEL) | VAF 45/155 reads (29%) | called by mutect2, pindel, varscan2
- CFAP57 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.429); called by muse, mutect2
- HTT | c.8174C>T p.T2725I | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- NCS1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OTOP3 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLEKHA6 | c.2434C>A p.P812T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2
- QRICH1 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 15/418 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2
- RPE | c.213G>A p.M71I (on ENST00000359429 / NM_001318926.1; = p.M3I on NM_006916.2) | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SEPTIN11 | c.158G>C p.G53A | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SERPINA1 | c.1087A>C p.T363P | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SLC5A9 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2
- XPO4 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF608 | c.3510del p.P1171Hfs*43 | Frame Shift Del (DEL) | VAF 51/143 reads (36%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.156G>A p.T52= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs371441582; called by muse, mutect2, varscan2
- CDCA2 | c.522C>T p.S174= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs745747711, COSV57945129; called by muse, mutect2, varscan2
- KRTAP13-4 | c.132T>A p.R44= | Silent (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- MTSS1 | c.604C>T p.L202= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs1008939204; called by muse, mutect2, varscan2
- PRAMEF2 | c.1233G>A p.T411= | Silent (SNP) | VAF 80/303 reads (26%) | catalogued as rs370982921; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPH3A | c.324G>T p.L108= (on ENST00000389385 / NM_001143854.2; = p.L104= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- SLC5A9 | c.681C>T p.L227= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1557472550; called by muse, varscan2
- SORT1 | c.1149C>A p.G383= | Silent (SNP) | VAF 17/180 reads (9%) | called by muse, mutect2
- WDR90 | c.741C>A p.L247= | Silent (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- CRIM1 | c.1501+51T>A | Intron (SNP) | VAF 22/108 reads (20%) | catalogued as rs1241168334; called by muse, mutect2, varscan2
- GABRG2 | c.1248+84G>A | Intron (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- GABRG2 | c.1248+435G>A | Intron (SNP) | VAF 16/54 reads (30%) | catalogued as rs1290963281, COSV62716503, COSV62720082; called by muse, mutect2
- GABRG2 | c.1249-629C>T | Intron (SNP) | VAF 20/108 reads (19%) | catalogued as rs756617271; called by muse, mutect2, varscan2
- LSS | c.*81G>A | 3'UTR (SNP) | VAF 56/200 reads (28%) | catalogued as rs530697328; called by muse, mutect2, varscan2
- SLC5A9 | c.692-20C>T | Intron (SNP) | VAF 28/97 reads (29%) | called by muse, varscan2
